Surgical pathology report (de-identified scan), TCGA case TCGA-DB-A4XD, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-A4XD-01A (Primary Tumor).

[page 1 of 3]
Final Diagnosis:

A-G. Brain, right temporal mass M-P, M-P+1 & M-P+2, cortex over right temporal mass, right temporal mass #1, #2, #3, biopsies and CUSA: Anaplastic astrocytoma (WHO grade III).

Immunostain p53 will be performed and reported in an addendum.

ADDENDA:

Immunohistochemical stains were performed on paraffin-embedded tissue using antibodies to p53. p53 protein is overexpressed in the majority of tumor cells.

AMENDMENTS:

Revision Description: Change "all submitted for permanent section only" to "Smears prepared. All submitted"

....Original Gross Description....

continued next page Page 1 of 3

1CD-0-3

Astrocytoma, anaplastic 9401/3
Site: Brain, temporal lobe C71.2

hw
10/23/12

[page 2 of 3]
A. Received fresh labeled "right temporal brain mass M-P" is a 0.7 x 0.6 x 0.5 cm portion of white matter. All submitted for permanent sections only. Grossed by

B. Received fresh labeled "cortex over right temporal brain mass" is a 2.5 x 1.3 x 1.1 cm portion of brain. All submitted for permanent sections only. Grossed by

C. Received fresh labeled "right temporal brain mass" is a 2.2 x 1.9 x 0.6 cm aggregate of tan-white soft tissue. Smears prepared. All submitted. Grossed by

D. Received fresh labeled "#2 right temporal brain mass" is a 4.5 x 2.8 x 1.4 cm portion of brain. All submitted for permanent sections only. Grossed by

E. Received fresh labeled "M-P +1 superior - right temporal brain mass" is a 2.3 x 1.6 x 0.8 cm aggregate of brain tissue. All submitted for permanent sections only. Grossed by

F. Received fresh labeled "M-P +2 inferior - right temporal brain mass" is a 2.0 x 1.5 x 1.0 cm portion of brain. All submitted for permanent sections only. Grossed by

G. Received fresh labeled "CUSA specimen trap - right temporal brain mass" is a 4.0 x 2.5 x 1.0 cm aggregate of brain. Representative sections are submitted. Grossed by

Signing Pathologist

Preliminary Frozen Section Consultation:

C. Brain, right temporal mass #1, smears: Diffuse glioma, favor astrocytoma. Hold over to type and grade.

Intraoperative cytologic smear(s) interpretation performed by:

Gross Description:

A. Received fresh labeled "right temporal brain mass M-P" is a 0.7 x 0.6 x 0.5 cm portion of white matter. All submitted for permanent sections only. Grossed by

B. Received fresh labeled "cortex over right temporal brain mass" is a 2.5 x 1.3 x 1.1 cm portion of brain. All submitted for permanent sections only. Grossed by

C. Received fresh labeled "right temporal brain mass" is a 2.2 x 1.9 x 0.6 cm aggregate of tan-white soft tissue. Smears prepared. All submitted. Grossed by

D. Received fresh labeled "#2 right temporal brain mass" is a 4.5 x 2.8 x 1.4 cm portion of brain. Smears prepared. All submitted. Grossed by

E. Received fresh labeled "M-P +1 superior - right temporal brain mass" is a 2.3 x 1.6 x 0.8 cm aggregate of brain tissue. All submitted for permanent sections only. Grossed by

F. Received fresh labeled "M-P +2 inferior - right temporal brain mass" is a 2.0 x 1.5 x 1.0 cm portion of brain. All submitted for permanent sections only. Grossed by

[page 3 of 3]
G. Received fresh labeled "CUSA specimen trap - right temporal brain mass" is a 4.0 x 2.5 x 1.0 cm aggregate of brain. Representative sections are submitted. Grossed by

Block Summary:

Part A: Right temporal brain mass M- P-

- 1 Rt temporal mass M-P

Part B: Cortex over right temporal brain mass

- 1 Cortex over Rt temporal 1
- 2 Cortex over Rt temporal 2
- 3 Cortex over Rt temporal 3

Part C: Right temporal brain mass

- 1 Rt temporal brain mass 1
- 2 Rt temporal brain mass 2
- 3 Rt temporal brain mass 3
- 4 Rt temporal brain mass 4

Part D: #2 right temporal brain mass

- 1 Rt temporal brain #2 (1)
- 2 Rt temporal brain #2 (2)
- 3 Rt temporal brain #2 (3)
- 4 Rt temporal brain #2 (4)
- 5 Rt temporal brain #2 (5)
- 6 Rt temporal brain #2 (6)

Part E: M P +1 superior right temporal brain mass

- 1 MP+1 Sup Rt temporal brain 1
- 2 MP+1 Sup Rt temporal brain 2

Part F: M P+2 inferior right temporal brain mass

- 1 MP+2 Inferior Rt temporal 1
- 2 MP+2 Inferior Rt temporal 2
- 3 MP+2 Inferior Rt temporal 3

Part G: CUSA specimen trap-Right temporal brain mass

- 1 Rt temporal brain mass 1
- 2 Rt temporal brain mass 2
- 3 Rt temporal brain mass 3

END OF REPORT

3 of 3
hw
10/24/12

Source: NCI Genomic Data Commons file 4fc5856b-f413-4ead-bf5c-90f491541a7e (TCGA-DB-A4XD.5D9BCE5F-0490-4504-B5A2-AB31EDD13605.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).